Gene-level copy-number profile of tumor specimen TCGA-ER-A3ET-06A from TCGA case TCGA-ER-A3ET, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 70.9 years (25,893 days).
Specimen TCGA-ER-A3ET-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.6fd8a59c-564c-4e06-a656-3737f5566c52.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ER-A3ET-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4ddc70b1-2d50-4507-9789-c7d8293d4d18

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 35; copy number 1: 5,779; copy number 2: 30,752; copy number 3: 15,955; copy number 4: 4,973; copy number 5: 1,244; copy number 6: 614; copy number 7: 23; copy number 8: 177; copy number 9: 34; copy number 10: 163; copy number 11: 19; copy number 12: 38.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ER-A3ET-06A-11D-A20B-01): tumor purity 0.6, ploidy 2.46, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:38,139,595–38,226,897, 1 gene (within-gene range 0–1): AC087473.1.
- chr18:7,455,844–7,461,135, 1 gene: AP001095.1.
- chr18:7,741,310–7,815,730, 2 genes: AP000897.2, AP000897.1.
- chr18:44,039,471–45,068,510, 9 genes (within-gene range 0–1): AC083760.1, RNA5SP455, AC110014.1, LINC01478, KRT8P5, MLECP1, SETBP1-DT, SETBP1, AC021766.1.
- chr18:59,685,820–60,301,317, 19 genes: AC010776.1, AC010776.2, AC010776.3, RPS26P54, GLUD1P4, AC098847.1, PMAIP1, AC107990.1, NFE2L3P1, RN7SL342P, ENTR1P1, AC090377.1, SINHCAFP2, RNU6-567P, AC090771.2, RPS3AP49, RNU4-17P, AC090771.1, AC090621.1.
- chr18:78,137,223–78,484,867, 2 genes: AC107892.1, AC087399.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,080 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:119,507,198–121,580,524, 58 genes, copy number 5: HSD3B1, GAPDHP32, HSD3BP3, GAPDHP27, HSD3BP4, GAPDHP33, LINC00622, HSD3BP5, ZNF697, PHGDH, HMGCS2, REG4, NBPF7, PFN1P9, NOTCH2P1, ADAM30, NOTCH2, AC245008.1, RNU6-465P, SEC22B, AC244669.2, 7SK, AC244669.1, U1, NBPF8, PFN1P2, AC241952.1, U2, 7SK, NOTCH2NLR, NBPF26, AC253572.1, RNVU1-19, PPIAL4A, AC241377.3, LINC00623, RNVU1-4, AC241377.4, AC241377.2, U1, AC241377.1, FCGR1B, AC244453.3, AC244453.2, H2BP1, AC244453.1, H3P4, RPL22P6, FAM72B, SRGAP2C, AC243994.1, SRGAP2-AS1, LINC02798, AL592494.1, MTIF2P1, AL592494.2, EMBP1, LINC01691.
- chr1:230,002,372–230,282,122, 2 genes, copy number 6 (within-gene range 3–6): LINC01736, GALNT2.
- chr1:232,700,204–232,983,882, 8 genes, copy number 5: RNU6-1211P, LINC01745, LINC01744, MAP10, RNU1-74P, AL122003.2, AL122003.1, NTPCR.
- chr1:240,775,514–248,919,946, 223 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr3:52,753,526–61,251,459, 116 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr3:94,506,766–98,088,102, 30 genes, copy number 5–10: ARMC10P1, AC140059.1, WDR82P1, LINC00879, RPS18P6, MTHFD2P1, AC106719.1, AC107304.1, HNRNPKP4, MIR8060, AC107015.1, RNU6-1094P, MTRNR2L12, RPL18AP8, RCC2P5, CDV3P1, AC109782.1, EPHA6, AC117470.1, AC110491.1, ARL6, AC110491.3, CRYBG3, AC110491.2, RIOX2, AC026100.1, GABRR3, OR5BM1P, OR5AC1, OR5AC2.
- chr3:98,100,793–98,105,672, 1 gene, copy number 8: OR5AC4P.
- chr3:98,902,424–106,427,977, 74 genes, copy number 10 (broad region; genes not listed).
- chr3:106,515,897–106,515,998, 1 gene, copy number 10: Y_RNA.
- chr4:53,377,839–54,295,272, 1 gene, copy number 5 (within-gene range 3–5): AC058822.1.
- chr4:53,659,208–56,761,485, 70 genes, copy number 5 (broad region; genes not listed).
- chr5:163,416,525–165,171,643, 16 genes, copy number 6 (within-gene range 4–6): AC008723.1, CCNG1, NUDCD2, HMMR, HMMR-AS1, MAT2B, AC010291.1, AC116917.1, RNU6-168P, AC008432.1, LSM1P2, AC008662.1, AC008662.2, AC109466.1, LINC02143, AC008446.1.
- chr5:178,113,532–181,342,213, 133 genes, copy number 5 (broad region; genes not listed).
- chr6:63,193,072–70,303,084, 53 genes, copy number 5–9 (within-gene range 3–9): AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3, EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2, AL355357.1, AL365217.1, SLC25A51P1, ADH5P4, NUFIP1P1, AL450336.1, RNU7-66P, AL591004.1, AL365503.1, RNA5SP208, RNU6-280P, Y_RNA, AL713998.1, AL713998.3, AL713998.4, AL713998.2, AL646090.2, AL646090.1, AL593844.1, LINC02549, AL606923.2, AL606923.1, AL391807.1, ADGRB3, LMBRD1, NPM1P37, GAPDHP42, COL19A1, RPL37P15, COL9A1, AL160262.1.
- chr6:85,949,690–86,436,138, 7 genes, copy number 5: AL450338.2, RNU4-12P, RPL7P27, RAB1AP2, NDUFA5P9, AL391417.1, RN7SL643P.
- chr8:150,584–13,632,574, 370 genes, copy number 6–12 (broad region; genes not listed).
- chr8:26,748,150–27,459,391, 13 genes, copy number 7 (within-gene range 2–7): ADRA1A, AC091675.1, COX6B1P4, AC067904.3, AC067904.1, MIR548H4, AC067904.2, AC090150.2, AC090150.1, STMN4, TRIM35, PTK2B, MIR6842.
- chr8:40,298,697–41,309,473, 11 genes, copy number 6 (within-gene range 3–6): SIRLNT, AC105999.1, AC010857.1, ZMAT4, AC048387.1, RNU6-356P, SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P.
- chr8:104,330,324–104,467,055, 1 gene, copy number 5 (within-gene range 4–5): DPYS.
- chr8:104,419,512–105,804,539, 13 genes, copy number 5 (within-gene range 4–5): AP003471.1, AP002847.1, MIR548A3, LRP12, NDUFA5P2, ZFPM2, AC012564.1, AC090142.2, AC090142.3, AC090142.1, AC021546.1, TMCC1P1, AC041039.1.
- chr14:21,924,063–22,490,553, 65 genes, copy number 6 (broad region; genes not listed).
- chr17:7,884,796–8,020,342, 10 genes, copy number 5 (within-gene range 2–5): CHD3, SCARNA21, RNF227, KCNAB3, AC104581.2, TRAPPC1, CNTROB, AC104581.1, GUCY2D, AC104581.3.
- chr17:9,021,510–11,564,063, 57 genes, copy number 5 (within-gene range 2–5): NTN1, AC005695.1, AC005695.3, STX8, AC005695.2, AC087501.1, AC087501.2, AC087501.3, AC087501.4, CFAP52, RPL19P18, AC118755.2, USP43, AC118755.1, AC027045.2, DHRS7C, AC027045.1, GSG1L2, AC027045.3, GLP2R, NPM1P45, RCVRN, GAS7, RPS27AP1, AC005291.2, MYH13, AC005291.1, AC005323.2, MYHAS, MYH8, MYH4, MYH1, MYH2, AC005323.1, MYH3, AC002347.1, SCO1, AC002347.2, ADPRM, TMEM220, MAGOH2P, TMEM220-AS1, AC015908.7, AC015908.3, AC015908.1, AC015908.4, AC015908.6, TMEM238L, AC015908.5, PIRT, AC015908.2, RNU6-1065P, RPL15P21, RN7SL601P, AC005548.1, SHISA6, AC005725.1.
- chr17:12,390,738–12,395,177, 1 gene, copy number 5: AC084167.1.
- chr17:77,959,240–83,095,122, 233 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr19:37,728,586–38,636,955, 36 genes, copy number 6: AC093227.1, AC093227.3, ZNF573, AC016582.2, AC016582.3, AC016582.1, WDR87, SIPA1L3, AC008395.1, AC011465.1, AC011479.3, AC011479.2, RN7SL663P, DPF1, SPINT2, PPP1R14A, AC011479.1, AC011479.4, Y_RNA, YIF1B, C19orf33, KCNK6, CATSPERG, AC005625.1, PSMD8, GGN, AC005789.1, SPRED3, FAM98C, RASGRP4, RYR1, AC067969.2, AC067969.1, MAP4K1, AC008649.1, EIF3K.
- chr22:17,116,297–24,712,520, 477 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,316. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
